Somatic mutation profile of tumor specimen TCGA-BQ-7059-01A (aliquot TCGA-BQ-7059-01A-11D-1961-08) from TCGA case TCGA-BQ-7059, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 71.6 years (26,136 days).
Specimen TCGA-BQ-7059-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5132ddd2-5265-4f6b-8f92-2d0a37d1ef3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7059-11A (Solid Tissue Normal), aliquot TCGA-BQ-7059-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89d4986d-beee-493b-ad40-7444f533424b

The open-access MAF lists 77 somatic variants for this specimen: 54 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 20, Frame Shift Ins 6, Frame Shift Del 5, Nonsense Mutation 2, 3'Flank 1, In Frame Ins 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3682G>C p.D1228H | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913671, CM970946, COSV59256021, COSV59261249; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AP002748.5 | c.529A>G p.N177D | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV59148694; called by muse, mutect2, varscan2
- ARHGEF4 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs376653204; called by mutect2, varscan2
- ATG2A | c.1214A>T p.Q405L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV65966829; called by muse, mutect2, varscan2
- ATG2B | c.2971G>C p.A991P | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as COSV63423130; called by muse, mutect2, varscan2
- ATXN2 | c.3086C>G p.A1029G (on ENST00000550104; = p.A869G on NM_002973.4) | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66483227; called by muse, mutect2, varscan2
- ATXN7L2 | c.1879C>A p.L627M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV60204845; called by muse, mutect2, varscan2
- BRWD1 | c.3936C>A p.N1312K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV60895829; called by muse, mutect2, varscan2
- C1orf21 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as COSV52405597; called by mutect2, varscan2
- CATSPERD | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.316); catalogued as COSV101062290; called by muse, varscan2
- CDON | c.1223T>A p.I408N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as COSV54997919; called by muse, mutect2, varscan2
- CEACAM5 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs199857011, COSV55752242; called by muse, mutect2, varscan2
- CELA2A | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV62747495; called by mutect2, varscan2
- CENPE | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs758681737, COSV54381121; ClinVar: uncertain significance; called by mutect2, varscan2
- CNTN6 | c.1323C>G p.I441M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs770736024, COSV63172149; called by muse, mutect2, varscan2
- DCXR | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60956241; called by mutect2, varscan2
- DOP1A | c.2176C>A p.Q726K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV52710350; called by muse, mutect2, varscan2
- DUSP11 | c.142A>G p.M48V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55594603; called by muse, mutect2, varscan2
- INSRR | c.3325A>C p.N1109H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as COSV63873148; called by muse, mutect2, varscan2
- ITPR3 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV65409147; called by muse, mutect2, varscan2
- MTHFD1 | c.2269A>C p.N757H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53700362; called by muse, mutect2, varscan2
- NAGS | c.854T>C p.L285P | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53227462; called by muse, mutect2, varscan2
- NOTCH3 | c.3796G>C p.G1266R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54641824, COSV99655478; called by mutect2, varscan2
- OGDH | c.319G>T p.V107L | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV56049838; called by muse, varscan2
- OSGIN2 | c.713G>C p.R238T | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.068); catalogued as COSV52408595; called by muse, mutect2, varscan2
- PER3 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV62705861; called by mutect2, varscan2
- PEX10 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56580288; called by muse, mutect2, varscan2
- PLEKHA6 | c.2746A>G p.K916E | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55333734; called by muse, mutect2, varscan2
- QTRT1 | c.886A>G p.T296A | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.018); catalogued as rs568561273, COSV51551424; called by muse, mutect2, varscan2
- RASIP1 | c.1873C>A p.H625N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as COSV55804830; called by mutect2, varscan2
- SBNO1 | c.2225A>G p.N742S (on ENST00000420886; = p.N741S on NM_018183.5) | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV57341669; called by muse, mutect2, varscan2
- SLC2A14 | c.358A>T p.I120F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV61586575; called by muse, mutect2, varscan2
- SLC2A8 | c.400T>A p.C134S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV59223938, COSV59226332; called by muse, mutect2, varscan2
- SLC30A9 | c.1322T>A p.L441H | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52556065; called by muse, mutect2, varscan2
- SLC38A1 | c.106A>T p.N36Y | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV67063522; called by muse, mutect2, varscan2
- SRRM2 | c.537T>A p.S179R | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV57073159; called by muse, mutect2, varscan2
- TCTN1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770297289, COSV66541202; called by muse, mutect2, varscan2
- TMED3 | c.176C>G p.T59S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV55302826; called by muse, mutect2, varscan2
- TXK | c.1253A>T p.D418V | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51915086; called by muse, mutect2, varscan2
- TXN2 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53397627; called by muse, mutect2, varscan2
- USH2A | c.9010C>A p.H3004N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV56369258; called by muse, mutect2, varscan2
- WDFY3 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.424); catalogued as rs1346720724, COSV55700956; called by muse, mutect2, varscan2
- DNAJC1 | c.975del p.K325Nfs*14 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel, varscan2
- GSN | c.1797dup p.S600Lfs*88 | Frame Shift Ins (INS) | VAF 13/75 reads (17%) | called by mutect2, pindel, varscan2
- H2AJ | c.281dup p.L94Ffs*55 (on ENST00000389078; = p.L94Ffs*87 on NM_177925.4) | Frame Shift Ins (INS) | VAF 53/159 reads (33%) | called by mutect2, pindel, varscan2
- HEATR3 | c.985_1001del p.G329Kfs*16 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel
- KLHL7 | c.207dup p.N70* (on ENST00000339077 / NM_001031710.3; = p.N22* on NM_018846.5) | Frame Shift Ins (INS) | VAF 22/75 reads (29%) | called by mutect2, varscan2
- MAML1 | c.1552dup p.L518Pfs*296 | Frame Shift Ins (INS) | VAF 18/81 reads (22%) | called by mutect2, pindel
- MCPH1 | c.1954dup p.M652Nfs*7 | Frame Shift Ins (INS) | VAF 61/259 reads (24%) | called by mutect2, pindel, varscan2
- NR3C2 | c.728del p.N243Ifs*23 | Frame Shift Del (DEL) | VAF 39/142 reads (27%) | called by mutect2, pindel, varscan2
- PHLDB1 | c.3217del p.A1073Qfs*40 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | called by pindel, varscan2*
- PTCHD3 | c.1854_1855insATATAC p.I617_Y618dup | In Frame Ins (INS) | VAF 18/96 reads (19%) | called by mutect2, varscan2
- TBC1D9B | c.968dup p.M323Ifs*34 | Frame Shift Ins (INS) | VAF 32/155 reads (21%) | called by mutect2, pindel, varscan2
- THRAP3 | c.2596del p.E866Kfs*30 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- ADAM32 | c.942A>G p.A314= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV65949295; called by muse, mutect2, varscan2
- CACNA1C | c.3291C>T p.D1097= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV59718558, COSV59733373; called by muse, mutect2, varscan2
- CSE1L | c.1089A>G p.E363= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV53701872; called by muse, mutect2, varscan2
- ELMO3 | c.195C>A p.I65= (on ENST00000652269; = p.I12= on NM_024712.5) | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV62606549; called by muse, mutect2, varscan2
- GPR32 | c.57G>C p.L19= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV54514550; called by muse, mutect2, varscan2
- GRIK4 | c.1095C>T p.F365= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV70802287; called by muse, mutect2, varscan2
- NR1D1 | c.87T>C p.P29= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs776537038, COSV99225183; called by muse, mutect2, varscan2
- PARP14 | c.678G>A p.V226= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV71734690; called by mutect2, varscan2
- PCDHGA11 | c.1644G>C p.S548= | Silent (SNP) | VAF 49/277 reads (18%) | catalogued as COSV53947486, COSV53984994; called by muse, mutect2, varscan2
- PNPLA6 | c.2565G>A p.Q855= (on ENST00000414982 / NM_001166111.2; = p.Q807= on NM_006702.5) | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV55378295; called by muse, mutect2, varscan2
- RAD50 | c.3622T>C p.L1208= | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as COSV54751370; called by muse, mutect2, varscan2
- SCAPER | c.642T>A p.R214= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV57740588; called by muse, varscan2
- STON2 | c.1305C>T p.H435= (on ENST00000649389 / NM_001366849.2; = p.H378= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as COSV50844627; called by muse, mutect2, varscan2
- THOC2 | c.1941T>C p.G647= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV55545895; called by muse, mutect2, varscan2
- TP53BP2 | c.2142T>C p.N714= (on ENST00000343537 / NM_001031685.3; = p.N585= on NM_005426.2) | Silent (SNP) | VAF 48/209 reads (23%) | catalogued as COSV59068573; called by muse, mutect2, varscan2
- TRIM38 | c.261G>C p.T87= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100837595, COSV62641695, COSV62642173; called by muse, varscan2
- VGLL3 | c.684G>A p.R228= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV67353000; called by mutect2, varscan2
- WSCD1 | c.858C>G p.P286= | Silent (SNP) | VAF 80/346 reads (23%) | catalogued as rs1290359709, COSV100496434, COSV58495624, COSV58496001; called by muse, mutect2, varscan2
- ZNF416 | c.1014T>C p.S338= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV52184507; called by muse, mutect2, varscan2
- ZNF830 | c.696T>C p.H232= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV58489188; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3860T>A | 3'UTR (SNP) | VAF 26/127 reads (20%) | catalogued as COSV53977227; called by muse, mutect2, varscan2
- N4BP2L1 | c.474-552G>A | Intron (SNP) | VAF 5/32 reads (16%) | called by mutect2, varscan2
- OGG1 | chr3:9759275 ins T | 3'Flank (INS) | VAF 26/151 reads (17%) | called by pindel, varscan2
